FM case AD17431 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/2c61e2c7-1528-40fa-a929-e6c464e239a6

Male, 57.2 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
